Somatic mutation profile of tumor specimen TCGA-AB-2820-03B (aliquot TCGA-AB-2820-03B-01W-0728-08) from TCGA case TCGA-AB-2820, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, minimal differentiation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.6 years (27,971 days).
Specimen TCGA-AB-2820-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64f5346a-86ca-4566-9a0c-d2e490b580d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2820-11B (Solid Tissue Normal), aliquot TCGA-AB-2820-11B-01W-0728-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a75c8e10-1de5-4382-8cb0-9f7f2506fa19

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Nonsense Mutation 2, Missense Mutation 1, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT1 | c.1207A>T p.K403* | Nonsense Mutation (SNP) | VAF 132/279 reads (47%) | catalogued as COSV101499511; called by muse, mutect2, varscan2
- FLNA | c.5146dup p.Q1716Pfs*77 (on ENST00000369850 / NM_001110556.2; = p.Q1708Pfs*77 on NM_001456.3) | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | catalogued as rs1557176615; called by pindel, varscan2
- KCND3 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 22/436 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV100138041; called by muse, mutect2
- TTC26 | c.967G>T p.G323* | Nonsense Mutation (SNP) | VAF 83/167 reads (50%) | catalogued as COSV58269252; called by muse, mutect2, varscan2
- IQCN | c.2946C>A p.A982= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV62746897; called by mutect2, varscan2
